Somatic mutation profile of tumor specimen TCGA-62-A470-01A (aliquot TCGA-62-A470-01A-11D-A24D-08) from TCGA case TCGA-62-A470, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 84.0 years (30,689 days).
Specimen TCGA-62-A470-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1013e4c-657f-439a-a3e6-7a63c651231a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-A470-10A (Blood Derived Normal), aliquot TCGA-62-A470-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dedaef8d-74fa-4e98-9d81-5ee7e50e4398

The open-access MAF lists 130 somatic variants for this specimen: 100 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 27, Nonsense Mutation 9, Frame Shift Del 4, Splice Site 3, RNA 2, In Frame Del 2, Splice Region 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1647T>A p.N549K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as rs1057520039, CM991150, COSV58820817, COSV58828526; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS4 | c.1349A>T p.Q450L | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV100917868; called by muse, mutect2, varscan2
- ADCYAP1 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.306); catalogued as rs748742011, COSV99327603; called by muse, mutect2, varscan2
- ALOX15 | c.1511A>G p.E504G | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV99541675; called by muse, mutect2, varscan2
- AMBP | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as rs777385730, COSV99469302; called by muse, mutect2, varscan2
- ANO2 | c.671C>T p.A224V (on ENST00000356134 / NM_001278597.3; = p.A228V on NM_001278596.3) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs1004961555, COSV100502527, COSV59043398; called by muse, mutect2, varscan2
- ANOS1 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV99391340; called by muse, mutect2
- ARHGEF11 | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100168898; called by muse, mutect2
- ASPH | c.2018G>T p.G673V | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101064367; called by muse, mutect2, varscan2
- BAZ2A | c.3301C>T p.R1101C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs745512484, COSV99467492; called by muse, mutect2, varscan2
- C1S | c.1124G>A p.S375N | Missense Mutation (SNP) | VAF 49/327 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100196766; called by muse, mutect2, varscan2
- C7 | c.683C>A p.S228* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100496483; called by muse, mutect2, varscan2
- CARD11 | c.2902G>A p.A968T | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs747530675, COSV67799074; called by muse, mutect2, varscan2
- CCDC85A | c.967G>T p.G323W | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1558577085, COSV101339545, COSV68154962; called by muse, mutect2, varscan2
- CCR2 | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 133/210 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV99432734; called by muse, mutect2, varscan2
- CDC42BPG | c.2948C>A p.A983D | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100712146; called by muse, varscan2
- CEACAM8 | c.703+2T>C p.X235_splice | Splice Site (SNP) | VAF 82/139 reads (59%) | catalogued as COSV99747827; called by muse, mutect2, varscan2
- CENPE | c.5101G>T p.E1701* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as COSV54390198, COSV99478375, COSV99479049; called by muse, mutect2, varscan2
- CNTNAP5 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV101444102; called by muse, mutect2, varscan2
- CPLX4 | c.347A>T p.E116V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100231525; called by muse, mutect2, varscan2
- CPLX4 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV55315109; called by muse, mutect2, varscan2
- CXCL9 | c.191+1G>T p.X64_splice | Splice Site (SNP) | VAF 44/270 reads (16%) | catalogued as COSV99345823; called by muse, mutect2, varscan2
- CXCR2 | c.942C>A p.Y314* | Nonsense Mutation (SNP) | VAF 64/155 reads (41%) | catalogued as COSV100579103; called by muse, mutect2, varscan2
- DIRAS2 | c.588C>A p.C196* | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as COSV101005828, COSV65370144; called by muse, mutect2, varscan2
- DOCK10 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746191772, COSV99291283; called by muse, mutect2, varscan2
- DOP1B | c.3236C>T p.P1079L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs144551122, COSV101215771; called by muse, mutect2, varscan2
- DYNC1H1 | c.7399C>T p.R2467C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100795326; called by muse, mutect2, varscan2
- EBI3 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV99696141; called by muse, mutect2, varscan2
- EEF2 | c.327_328insT p.D110* | Frame Shift Ins (INS) | VAF 13/51 reads (25%) | catalogued as COSV100500966; called by mutect2, pindel, varscan2
- EFS | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99391758; called by muse, mutect2, varscan2
- ETNK1 | c.461A>T p.H154L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as COSV56883862; called by muse, mutect2, varscan2
- FAM227B | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.203); catalogued as COSV100175532; called by muse, mutect2, varscan2
- FCHSD2 | c.1512G>T p.M504I | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100238991; called by muse, mutect2, varscan2
- FLT3 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99610010; called by muse, mutect2, varscan2
- GRM7 | c.422C>A p.P141Q | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.042); catalogued as COSV63165469; called by muse, mutect2
- GRM7 | c.1260C>A p.H420Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100738210; called by muse, mutect2, varscan2
- GSS | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99404584; called by muse, mutect2, varscan2
- GUCA1A | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99274262; called by muse, mutect2, varscan2
- HERC2 | c.13829G>C p.G4610A | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV99876405; called by muse, mutect2, varscan2
- HSD17B4 | c.1755+1G>C p.X585_splice (on ENST00000414835 / NM_001199291.3; = p.X560_splice on NM_000414.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 7/81 reads (9%) | catalogued as COSV99820115; called by muse, mutect2
- HSP90B1 | c.1490T>A p.I497N | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100236725; called by muse, mutect2, varscan2
- ID2 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99301137; called by muse, mutect2, varscan2
- IGFBP1 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV99298830; called by muse, mutect2
- INPP4A | c.1016A>G p.H339R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1359464092, COSV99305103; called by muse, mutect2, varscan2
- KIAA1328 | c.390T>A p.F130L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV99695196; called by muse, mutect2
- LAMC3 | c.4663G>C p.A1555P | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV55991291, COSV99908310; called by muse, mutect2, varscan2
- LINGO3 | c.539C>T p.T180I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs749434099, COSV101347279; called by muse, mutect2, varscan2
- LLGL2 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as rs763984358, COSV51419651; called by muse, mutect2, varscan2
- LRFN5 | c.1208C>A p.S403* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99985227; called by muse, mutect2, varscan2
- LRRIQ3 | c.761A>T p.E254V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV100599355; called by muse, mutect2, varscan2
- LYPD3 | c.137C>G p.P46R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV99746859, COSV99747217, COSV99747236; called by muse, mutect2, varscan2
- MLLT10 | c.2125C>G p.L709V (on ENST00000307729 / NM_001195626.3; = p.L725V on NM_004641.3) | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV100308701; called by muse, mutect2, varscan2
- MYO18B | c.811C>G p.Q271E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.039); catalogued as COSV100124949; called by muse, mutect2, varscan2
- MYOF | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs555479300, COSV63703270, COSV63704165; called by muse, mutect2, varscan2
- NECTIN1 | c.329G>C p.R110P | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.399); catalogued as COSV50599523, COSV99872571; called by muse, mutect2, varscan2
- NLE1 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV100681128; called by mutect2, varscan2
- NLGN4X | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV52032997, COSV99323631; called by muse, mutect2, varscan2
- OR2G2 | c.32A>C p.N11T | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100189955, COSV60742480; called by muse, mutect2, varscan2
- OR4C6 | c.325G>T p.G109W | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100051547, COSV58603820; called by muse, mutect2, varscan2
- OR4N2 | c.892A>G p.M298V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs750447313, COSV100269937; called by muse, mutect2, varscan2
- OR52B6 | c.887T>A p.L296Q | Missense Mutation (SNP) | VAF 89/233 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100798533; called by muse, mutect2, varscan2
- OR5D14 | c.508T>G p.F170V | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59456459; called by muse, mutect2, varscan2
- PCDH11Y | c.7A>T p.R3W | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as COSV99292515; called by muse, mutect2, varscan2
- PCDH17 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.481); catalogued as rs767421658, COSV100931937; called by muse, mutect2, varscan2
- PJA2 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs1326652312, COSV100754521; called by muse, mutect2, varscan2
- PLEC | c.11265G>A p.M3755I (on ENST00000322810 / NM_201380.4; = p.M3645I on NM_000445.5) | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV59629569; called by muse, mutect2, varscan2
- PPIP5K2 | c.3171G>A p.G1057= | Splice Region (SNP) | VAF 20/35 reads (57%) | catalogued as COSV100384186; called by muse, mutect2, varscan2
- RGS7 | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.129); catalogued as COSV100470493; called by muse, mutect2, varscan2
- RIMBP2 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV99900304; called by muse, varscan2
- RPL22 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV99329918; called by muse, mutect2, varscan2
- RPS3A | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99923760; called by muse, mutect2, varscan2
- SCN2A | c.5705G>T p.R1902L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51849749, COSV99333166; called by muse, mutect2, varscan2
- SCRT2 | c.473C>A p.A158D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV99857273; called by muse, mutect2
- SEC62 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs762601555, COSV61262536; called by muse, mutect2, varscan2
- SF1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99918719; called by muse, mutect2, varscan2
- SHANK1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99521867; called by muse, mutect2, varscan2
- SLC27A4 | c.237G>T p.L79F | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV100056639; called by muse, mutect2, varscan2
- SNCB | c.188C>A p.A63D | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100031366; called by muse, mutect2, varscan2
- SPAG16 | c.1009C>G p.P337A | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100535196; called by muse, mutect2
- SPATA18 | c.1135G>T p.V379F | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV54648562; called by muse, mutect2, varscan2
- STAMBPL1 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV100905161; called by muse, mutect2, varscan2
- TICRR | c.5388T>A p.D1796E | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV99179486; called by muse, mutect2, varscan2
- TNRC6B | c.4892G>T p.R1631L (on ENST00000454349 / NM_001162501.2; = p.R1521L on NM_015088.3) | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100110382; called by muse, mutect2, varscan2
- TOM1L1 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.757); catalogued as rs371309084; called by muse, mutect2, varscan2
- TPD52L3 | c.359C>A p.S120Y | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368824558, COSV100096120; called by muse, mutect2, varscan2
- TSHZ1 | c.1117G>C p.E373Q (on ENST00000580243 / NM_001308210.2; = p.E328Q on NM_005786.6) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.029); catalogued as COSV100433901; called by muse, mutect2, varscan2
- UBE2V2 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs772913593, COSV101568635; called by muse, mutect2, varscan2
- WFDC3 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376220123; called by muse, mutect2, varscan2
- ZNF557 | c.917T>C p.I306T (on ENST00000414706 / NM_001044388.2; = p.I313T on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV99422711; called by muse, mutect2, varscan2
- ATP10D | c.555C>A p.C185* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2
- IGHV4-61 | c.143T>A p.V48D | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); called by muse, mutect2
- KEAP1 | c.1376_1382del p.R459Pfs*39 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- KIAA1549 | c.1981_1986del p.Q661_S662del | In Frame Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- MSMB | c.154T>A p.W52R | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTDH | c.401_407del p.E134Vfs*12 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- SH3KBP1 | c.908_915del p.D303Vfs*16 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- TUSC3 | c.843_853del p.H282Gfs*15 | Frame Shift Del (DEL) | VAF 4/52 reads (8%) | called by mutect2, pindel
- ZNF142 | c.4157_4177del p.M1386_L1392del (on ENST00000411696 / NM_001379660.1; = p.M1186_L1192del on NM_001105537.4 and 5 other RefSeq transcripts) | In Frame Del (DEL) | VAF 18/82 reads (22%) | called by mutect2, pindel
- ADCY2 | c.1560C>T p.N520= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs761978082, COSV57881277; called by muse, mutect2, varscan2
- ADGRG4 | c.3339A>T p.S1113= | Silent (SNP) | VAF 95/142 reads (67%) | catalogued as COSV99796492; called by muse, mutect2, varscan2
- AGBL5 | c.1335C>T p.Y445= | Silent (SNP) | VAF 36/239 reads (15%) | catalogued as rs760778106, COSV100549397; called by muse, mutect2, varscan2
- BACH2 | c.1593C>T p.D531= | Silent (SNP) | VAF 48/89 reads (54%) | catalogued as rs201225316, COSV57585469, COSV57591025; called by muse, mutect2, varscan2
- C6 | c.237C>A p.P79= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs1460652867, CD961874, COSV54711307, COSV54714263; called by muse, mutect2, varscan2
- CFTR | c.1773C>G p.V591= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV99139101; called by muse, mutect2, varscan2
- CLEC16A | c.2646C>T p.F882= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs201690645, COSV55490032; called by muse, mutect2, varscan2
- CORO7 | c.1608G>T p.T536= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as COSV52028826, COSV99228065; called by muse, mutect2, varscan2
- EGR3 | c.396A>G p.P132= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs370729228; called by muse, mutect2, varscan2
- FAAP100 | c.1716C>T p.L572= | Silent (SNP) | VAF 27/156 reads (17%) | catalogued as rs562962178, COSV100585574; called by muse, mutect2, varscan2
- GPR88 | c.267G>T p.A89= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100159597; called by muse, mutect2
- IGKV2-30 | c.213C>A p.R71= | Silent (SNP) | VAF 44/259 reads (17%) | catalogued as rs778612152; called by muse, mutect2, varscan2
- KDM4C | c.1632C>A p.I544= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV101185086; called by muse, mutect2, varscan2
- KIAA1217 | c.213G>A p.G71= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as rs141733021, COSV64600630, COSV64607232; called by muse, mutect2, varscan2
- MGA | c.2940A>G p.Q980= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as rs376537329; called by muse, mutect2, varscan2
- MRPS18C | c.9T>C p.A3= | Silent (SNP) | VAF 184/373 reads (49%) | catalogued as rs759861855, COSV99788072; called by muse, mutect2, varscan2
- NANS | c.1035C>T p.I345= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99271477; called by muse, mutect2, varscan2
- OSTN | c.399C>A p.G133= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100174321; called by muse, mutect2, varscan2
- PNPLA7 | c.957C>T p.G319= | Silent (SNP) | VAF 15/192 reads (8%) | catalogued as rs758786549, COSV53004429, COSV99481095; called by muse, mutect2
- SLC26A1 | c.660G>A p.E220= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs777126025, COSV101272546; called by muse, varscan2
- SOWAHD | c.885C>A p.G295= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV100673173; called by muse, mutect2, varscan2
- SUCLG2 | c.1170G>A p.V390= | Silent (SNP) | VAF 38/145 reads (26%) | catalogued as COSV100214799; called by muse, mutect2, varscan2
- TBX18 | c.1773C>A p.T591= | Silent (SNP) | VAF 37/61 reads (61%) | catalogued as COSV63736119; called by muse, mutect2, varscan2
- TEX15 | c.1965A>T p.S655= (on ENST00000256246; = p.S1038= on NM_001350162.2) | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV56341181; called by muse, mutect2, varscan2
- TTN | c.14358A>C p.P4786= (on ENST00000591111; = p.P3859= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV100626914; called by muse, mutect2, varscan2
- TTN | c.12435T>A p.V4145= (on ENST00000591111; = p.V4099= on NM_003319.4) | Silent (SNP) | VAF 10/164 reads (6%) | catalogued as COSV100626916; called by muse, mutect2
- UBXN4 | c.180C>G p.T60= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99739542; called by muse, mutect2
- OR2W5 | n.788G>A | RNA (SNP) | VAF 26/135 reads (19%) | catalogued as rs745508378; called by muse, mutect2, varscan2
- SSPOP | n.11900C>A | RNA (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100947942; called by muse, mutect2
- VKORC1 | c.173+254G>T | Intron (SNP) | VAF 46/377 reads (12%) | catalogued as rs1389700243, COSV100161838; called by muse, mutect2, varscan2
